Somatic mutation profile of tumor specimen TCGA-HE-A5NK-01A (aliquot TCGA-HE-A5NK-01A-11D-A26P-10) from TCGA case TCGA-HE-A5NK, project TCGA-KIRP (Kidney Renal Papillary Cell Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Papillary adenocarcinoma, NOS; Tissue or organ of origin: Kidney, NOS.
Specimen TCGA-HE-A5NK-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 188a5d66-f609-4caa-bc21-910ac6c77172.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-HE-A5NK-10A (Blood Derived Normal), aliquot TCGA-HE-A5NK-10A-01D-A26P-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/ee576149-0a7f-4c80-84b0-8d5de14df6f2

The open-access MAF lists 106 somatic variants for this specimen: 76 protein-altering or splice-affecting, 23 silent, 7 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 60, Silent 23, Frame Shift Del 8, Nonsense Mutation 4, Intron 3, 3'UTR 3, Frame Shift Ins 3, 5'UTR 1, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TMEM43 | c.1073C>T p.S358L | Missense Mutation (SNP) | VAF 14/154 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.962); catalogued as rs63750743, CM081452, COSV53206958; ClinVar: pathogenic; called by muse, mutect2
- A2M | c.2599A>T p.N867Y | Missense Mutation (SNP) | VAF 32/156 reads (21%) | SIFT deleterious (0.03); PolyPhen benign (0.014); catalogued as COSV59390627; called by muse, mutect2, varscan2
- ABCB6 | c.2362G>T p.V788L | Missense Mutation (SNP) | VAF 26/166 reads (16%) | SIFT deleterious (0.01); PolyPhen benign (0.165); catalogued as COSV54698906; called by muse, mutect2, varscan2
- ADAMTS6 | c.1397A>T p.N466I | Missense Mutation (SNP) | VAF 46/298 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV66863022; called by muse, mutect2, varscan2
- AGTPBP1 | c.2264G>C p.G755A (on ENST00000357081 / NM_001330701.2; = p.G715A on NM_015239.2) | Missense Mutation (SNP) | VAF 25/121 reads (21%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.872); catalogued as COSV61275326; called by muse, mutect2, varscan2
- AKAP9 | c.1990A>T p.K664* | Nonsense Mutation (SNP) | VAF 6/50 reads (12%) | catalogued as COSV62354041; called by muse, mutect2, varscan2
- ALDH8A1 | c.494T>C p.I165T | Missense Mutation (SNP) | VAF 17/123 reads (14%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.928); catalogued as rs755804167, COSV55643567; called by muse, mutect2, varscan2
- AOC3 | c.1289G>A p.C430Y | Missense Mutation (SNP) | VAF 78/484 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53828102; called by muse, mutect2
- APEH | c.1256T>C p.L419P | Missense Mutation (SNP) | VAF 63/247 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.885); catalogued as COSV56535853; called by muse, mutect2, varscan2
- AQP11 | c.509A>G p.E170G | Missense Mutation (SNP) | VAF 37/189 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57992966; called by muse, mutect2, varscan2
- ARSI | c.376C>G p.L126V | Missense Mutation (SNP) | VAF 9/300 reads (3%) | SIFT deleterious (0.03); PolyPhen benign (0.158); catalogued as COSV100156058; called by muse, mutect2
- CCP110 | c.1829A>T p.E610V | Missense Mutation (SNP) | VAF 38/232 reads (16%) | SIFT deleterious (0.05); PolyPhen benign (0.391); catalogued as COSV66817618; called by muse, mutect2
- CCP110 | c.1831C>A p.Q611K | Missense Mutation (SNP) | VAF 38/232 reads (16%) | SIFT deleterious (0.01); PolyPhen benign (0.359); catalogued as COSV66817624; called by muse, mutect2
- CNGA4 | c.844G>C p.D282H | Missense Mutation (SNP) | VAF 45/270 reads (17%) | SIFT deleterious (0); PolyPhen benign (0.007); catalogued as COSV66006662; called by muse, mutect2, varscan2
- COL6A5 | c.514G>T p.A172S | Missense Mutation (SNP) | VAF 19/146 reads (13%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.968); catalogued as COSV55211536, COSV55215820; called by muse, mutect2, varscan2
- COL7A1 | c.8173G>T p.G2725W | Missense Mutation (SNP) | VAF 14/73 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56476995; called by muse, mutect2, varscan2
- COL9A1 | c.2684C>A p.P895H | Missense Mutation (SNP) | VAF 42/165 reads (25%) | SIFT tolerated (0.1); PolyPhen benign (0.245); catalogued as COSV57889825; called by muse, mutect2, varscan2
- COQ8A | c.1582G>A p.A528T | Missense Mutation (SNP) | VAF 16/57 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.91); catalogued as COSV100503370, COSV62017165; called by muse, mutect2, varscan2
- CPS1 | c.2132G>T p.C711F | Missense Mutation (SNP) | VAF 48/257 reads (19%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.741); catalogued as COSV51819438; called by muse, mutect2, varscan2
- CST9L | c.269A>C p.E90A | Missense Mutation (SNP) | VAF 63/317 reads (20%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.783); catalogued as COSV65408147; called by muse, mutect2, varscan2
- DDI2 | c.382T>G p.S128A | Missense Mutation (SNP) | VAF 35/124 reads (28%) | SIFT tolerated (0.41); PolyPhen benign (0); catalogued as COSV60780783; called by muse, mutect2, varscan2
- DHX35 | c.1777C>T p.Q593* | Nonsense Mutation (SNP) | VAF 40/211 reads (19%) | catalogued as COSV52672825; called by muse, mutect2, varscan2
- DOT1L | c.1327C>T p.Q443* | Nonsense Mutation (SNP) | VAF 32/140 reads (23%) | catalogued as COSV101288696; called by muse, mutect2, varscan2
- EIF3H | c.722A>C p.K241T | Missense Mutation (SNP) | VAF 35/141 reads (25%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.922); catalogued as COSV52670655; called by muse, mutect2, varscan2
- EIF4E2 | c.303G>T p.M101I | Missense Mutation (SNP) | VAF 45/233 reads (19%) | SIFT tolerated (0.11); PolyPhen benign (0.003); catalogued as COSV51472852; called by muse, mutect2, varscan2
- FGF3 | c.542G>A p.R181H | Missense Mutation (SNP) | VAF 6/114 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs782147248, COSV61925745; called by muse, mutect2
- FMN2 | c.2465A>T p.Q822L | Missense Mutation (SNP) | VAF 29/114 reads (25%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.147); catalogued as COSV60444743; called by muse, mutect2, varscan2
- GRAMD1A | c.137A>C p.D46A | Missense Mutation (SNP) | VAF 20/126 reads (16%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.698); catalogued as COSV58768282; called by muse, mutect2, varscan2
- HEG1 | c.518G>A p.S173N | Missense Mutation (SNP) | VAF 52/222 reads (23%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as COSV60764388; called by muse, mutect2, varscan2
- HIP1R | c.1990G>A p.A664T | Missense Mutation (SNP) | VAF 55/235 reads (23%) | SIFT tolerated (0.3); PolyPhen benign (0.01); catalogued as rs375880257; called by muse, mutect2, varscan2
- IGLV5-37 | c.287A>C p.N96T | Missense Mutation (SNP) | VAF 23/102 reads (23%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.549); catalogued as rs777979333; called by muse, mutect2, varscan2
- IKZF2 | c.1016A>G p.H339R | Missense Mutation (SNP) | VAF 38/204 reads (19%) | SIFT tolerated (0.85); PolyPhen probably damaging (0.989); catalogued as COSV59582148; called by muse, mutect2, varscan2
- ITGAX | c.1291G>C p.G431R | Missense Mutation (SNP) | VAF 107/481 reads (22%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as COSV51649480, COSV51650429; called by muse, mutect2, varscan2
- KAT6A | c.3181T>A p.L1061I | Missense Mutation (SNP) | VAF 55/264 reads (21%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.991); catalogued as COSV55910226; called by muse, mutect2, varscan2
- KLHL24 | c.1079C>A p.A360D | Missense Mutation (SNP) | VAF 10/100 reads (10%) | SIFT deleterious (0.01); PolyPhen benign (0.392); catalogued as COSV54427925, COSV54428026; called by muse, mutect2, varscan2
- KRBA1 | c.2770C>G p.P924A | Missense Mutation (SNP) | VAF 10/48 reads (21%) | SIFT tolerated (0.27); PolyPhen possibly damaging (0.508); catalogued as rs1296436064, COSV55443253; called by muse, mutect2, varscan2
- LPA | c.56C>A p.P19H | Missense Mutation (SNP) | VAF 15/102 reads (15%) | SIFT tolerated, low confidence (0.11); PolyPhen possibly damaging (0.873); catalogued as COSV100307617; called by muse, mutect2, varscan2
- LY9 | c.1251A>C p.R417S | Missense Mutation (SNP) | VAF 55/222 reads (25%) | SIFT tolerated (0.08); PolyPhen benign (0.038); catalogued as COSV54436379; called by muse, mutect2, varscan2
- MAP1A | c.4117A>G p.T1373A | Missense Mutation (SNP) | VAF 51/161 reads (32%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.116); catalogued as COSV55811364; called by muse, mutect2, varscan2
- METTL2B | c.278G>T p.R93I | Missense Mutation (SNP) | VAF 54/396 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52310228; called by muse, mutect2, varscan2
- MTRF1 | c.1237G>A p.G413S | Missense Mutation (SNP) | VAF 35/162 reads (22%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV65263700; called by muse, mutect2, varscan2
- MTUS1 | c.514T>C p.F172L | Missense Mutation (SNP) | VAF 35/210 reads (17%) | SIFT deleterious (0.04); PolyPhen benign (0.416); catalogued as COSV50574685; called by muse, mutect2, varscan2
- NEB | c.12310T>A p.Y4104N | Missense Mutation (SNP) | VAF 30/142 reads (21%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.998); catalogued as COSV51443279, COSV99422553; called by muse, mutect2, varscan2
- NOLC1 | c.508G>A p.D170N | Missense Mutation (SNP) | VAF 31/181 reads (17%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.78); catalogued as COSV64180227, COSV64180871; called by muse, mutect2, varscan2
- NR3C2 | c.1597A>G p.I533V | Missense Mutation (SNP) | VAF 52/204 reads (25%) | SIFT tolerated (0.1); PolyPhen benign (0.205); catalogued as rs1183657431, COSV60996945; called by muse, mutect2, varscan2
- PHPT1 | c.278A>G p.Y93C | Missense Mutation (SNP) | VAF 28/163 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56034388; called by muse, mutect2, varscan2
- PKHD1 | c.7213C>A p.Q2405K | Missense Mutation (SNP) | VAF 27/121 reads (22%) | SIFT tolerated (0.07); PolyPhen benign (0.167); catalogued as COSV61889212; called by muse, mutect2, varscan2
- RBM14 | c.293T>C p.L98P | Missense Mutation (SNP) | VAF 8/61 reads (13%) | SIFT deleterious (0.01); PolyPhen benign (0.398); catalogued as COSV59560162; called by muse, mutect2, varscan2
- REPIN1 | c.842C>A p.S281* | Nonsense Mutation (SNP) | VAF 9/51 reads (18%) | catalogued as rs1282527528, COSV101262720, COSV68292780; called by muse, mutect2
- RTL3 | c.559C>T p.P187S | Missense Mutation (SNP) | VAF 18/45 reads (40%) | SIFT tolerated (0.27); PolyPhen benign (0); catalogued as COSV58185170; called by muse, mutect2, varscan2
- SCAF8 | c.3335G>A p.G1112D | Missense Mutation (SNP) | VAF 37/196 reads (19%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as COSV65793189; called by muse, mutect2, varscan2
- SEPTIN7 | c.799T>A p.Y267N | Missense Mutation (SNP) | VAF 29/152 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV63256202; called by muse, mutect2, varscan2
- SHANK3 | c.3544G>A p.E1182K | Missense Mutation (SNP) | VAF 35/192 reads (18%) | SIFT deleterious (0.04); PolyPhen benign (0.308); catalogued as COSV53187424; called by muse, mutect2, varscan2
- SLC15A2 | c.1648A>G p.T550A | Missense Mutation (SNP) | VAF 29/185 reads (16%) | SIFT tolerated (0.93); PolyPhen benign (0); catalogued as COSV55199824; called by muse, mutect2, varscan2
- SMARCC1 | c.1672G>T p.V558L | Missense Mutation (SNP) | VAF 17/121 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as COSV54383393, COSV54384378; called by muse, mutect2, varscan2
- SMC1B | c.1694C>G p.A565G | Missense Mutation (SNP) | VAF 32/154 reads (21%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.598); catalogued as COSV62532339; called by muse, mutect2, varscan2
- SMC1B | c.1693G>A p.A565T | Missense Mutation (SNP) | VAF 32/154 reads (21%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.598); catalogued as COSV62532348; called by muse, mutect2, varscan2
- STPG2 | c.835A>G p.K279E | Missense Mutation (SNP) | VAF 39/203 reads (19%) | SIFT tolerated (0.6); PolyPhen benign (0.015); catalogued as COSV54812631; called by muse, mutect2, varscan2
- TAS2R39 | c.130G>A p.E44K | Missense Mutation (SNP) | VAF 13/188 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.96); catalogued as rs963789238, COSV71470972; called by muse, mutect2
- TBL1XR1 | c.108G>C p.Q36H | Missense Mutation (SNP) | VAF 6/156 reads (4%) | SIFT deleterious (0.05); PolyPhen benign (0.091); catalogued as COSV61792034; called by muse, mutect2
- TSPAN16 | c.251G>A p.R84K | Missense Mutation (SNP) | VAF 40/202 reads (20%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.992); catalogued as COSV57443092; called by muse, mutect2, varscan2
- WDFY3 | c.3205C>A p.P1069T | Missense Mutation (SNP) | VAF 95/359 reads (26%) | SIFT tolerated (0.28); PolyPhen benign (0.006); catalogued as COSV55710059, COSV99883502; called by muse, mutect2, varscan2
- WWP1 | c.919G>C p.A307P | Missense Mutation (SNP) | VAF 18/106 reads (17%) | SIFT tolerated (0.18); PolyPhen benign (0.003); catalogued as COSV55362463; called by muse, mutect2, varscan2
- ZNF418 | c.827A>T p.H276L | Missense Mutation (SNP) | VAF 32/162 reads (20%) | SIFT deleterious (0); PolyPhen benign (0.127); catalogued as COSV68676221; called by muse, mutect2, varscan2
- CACNA1D | c.6192del p.V2065Sfs*2 (on ENST00000350061 / NM_001128840.3; = p.V2085Sfs*2 on NM_000720.4) | Frame Shift Del (DEL) | VAF 74/459 reads (16%) | called by mutect2, pindel, varscan2
- CCDC112 | c.1332_1333dup p.R445Kfs*12 | Frame Shift Ins (INS) | VAF 27/213 reads (13%) | called by mutect2, pindel, varscan2
- CNGA1 | c.1522del p.I508Sfs*27 | Frame Shift Del (DEL) | VAF 24/172 reads (14%) | called by mutect2, pindel, varscan2
- DNHD1 | c.3516del p.F1172Lfs*27 | Frame Shift Del (DEL) | VAF 18/216 reads (8%) | called by mutect2, pindel
- IQGAP3 | c.2252_2253del p.A751Gfs*24 | Frame Shift Del (DEL) | VAF 27/125 reads (22%) | called by mutect2, pindel, varscan2
- MAML2 | c.3143dup p.N1048Kfs*14 | Frame Shift Ins (INS) | VAF 47/210 reads (22%) | called by mutect2, pindel, varscan2
- MMD | c.312_313dup p.Y105Sfs*13 | Frame Shift Ins (INS) | VAF 24/106 reads (23%) | called by mutect2, pindel, varscan2
- NPTX2 | c.1123del p.Q375Sfs*124 | Frame Shift Del (DEL) | VAF 39/229 reads (17%) | called by mutect2, varscan2
- RBMXL1 | c.84del p.F28Lfs*7 | Frame Shift Del (DEL) | VAF 38/406 reads (9%) | called by mutect2, pindel
- RNF213 | c.13224_13226del p.K4408_I4409delinsN | In Frame Del (DEL) | VAF 28/233 reads (12%) | called by mutect2, pindel, varscan2
- SAV1 | c.326_327del p.E109Vfs*12 | Frame Shift Del (DEL) | VAF 114/642 reads (18%) | called by pindel, varscan2
- YEATS2 | c.1568del p.K523Rfs*25 | Frame Shift Del (DEL) | VAF 48/362 reads (13%) | called by mutect2, pindel, varscan2
- ABCB6 | c.2361T>C p.T787= | Silent (SNP) | VAF 26/169 reads (15%) | catalogued as COSV54698935; called by muse, mutect2, varscan2
- BCL2L2 | c.9C>A p.T3= | Silent (SNP) | VAF 24/76 reads (32%) | catalogued as COSV51636493; called by muse, mutect2, varscan2
- BMP15 | c.537C>T p.N179= | Silent (SNP) | VAF 73/207 reads (35%) | catalogued as COSV53141374; called by muse, mutect2, varscan2
- CACNA1C | c.4131C>T p.I1377= | Silent (SNP) | VAF 26/102 reads (25%) | catalogued as rs770774627, COSV59754002, COSV59754317; called by muse, mutect2, varscan2
- CACNA1E | c.2406G>A p.A802= | Silent (SNP) | VAF 44/341 reads (13%) | catalogued as rs1192075910, COSV62409847; called by muse, mutect2, varscan2
- CPLANE1 | c.8962T>C p.L2988= | Silent (SNP) | VAF 220/651 reads (34%) | catalogued as rs1252246154, COSV57069236; called by muse, mutect2, varscan2
- CRIP3 | c.627A>G p.V209= | Silent (SNP) | VAF 38/202 reads (19%) | catalogued as rs745436154, COSV51485106; called by muse, mutect2, varscan2
- DEFB113 | c.81A>G p.E27= | Silent (SNP) | VAF 14/78 reads (18%) | catalogued as rs1370054918, COSV59038347; called by muse, mutect2, varscan2
- FUBP1 | c.1797T>C p.A599= | Silent (SNP) | VAF 13/64 reads (20%) | catalogued as COSV53936038; called by muse, mutect2, varscan2
- GRAP2 | c.972C>T p.Y324= | Silent (SNP) | VAF 28/105 reads (27%) | catalogued as rs777777879, COSV59996465; called by muse, mutect2, varscan2
- HAPLN4 | c.381C>T p.S127= | Silent (SNP) | VAF 12/48 reads (25%) | catalogued as COSV52270737; called by muse, mutect2, varscan2
- KCNH6 | c.1941C>G p.V647= | Silent (SNP) | VAF 61/301 reads (20%) | catalogued as COSV59006321; called by muse, mutect2, varscan2
- LRRC8C | c.1059T>C p.Y353= | Silent (SNP) | VAF 34/140 reads (24%) | catalogued as rs778202494, COSV65000086; called by muse, mutect2, varscan2
- MYO18B | c.6732C>T p.P2244= | Silent (SNP) | VAF 28/153 reads (18%) | catalogued as COSV59143471; called by muse, mutect2, varscan2
- NAF1 | c.744A>G p.A248= | Silent (SNP) | VAF 5/40 reads (13%) | catalogued as rs1219478808, COSV56805441; called by muse, mutect2, varscan2
- OR2AG2 | c.819C>A p.I273= | Silent (SNP) | VAF 78/423 reads (18%) | catalogued as COSV58454689, COSV58455838; called by muse, mutect2, varscan2
- PLIN2 | c.180G>T p.V60= | Silent (SNP) | VAF 47/247 reads (19%) | catalogued as COSV52804057; called by muse, mutect2, varscan2
- PRR14 | c.846G>A p.L282= | Silent (SNP) | VAF 5/34 reads (15%) | catalogued as COSV54913133; called by muse, mutect2, varscan2
- PTPRB | c.186C>T p.T62= | Silent (SNP) | VAF 71/347 reads (20%) | catalogued as COSV54248986; called by muse, mutect2, varscan2
- SLC19A2 | c.450C>T p.D150= | Silent (SNP) | VAF 50/167 reads (30%) | catalogued as COSV52548459; called by muse, mutect2, varscan2
- SLC9A8 | c.48T>C p.H16= | Silent (SNP) | VAF 40/167 reads (24%) | catalogued as rs536021956, COSV64290166; called by muse, mutect2, varscan2
- UTP15 | c.318T>A p.L106= | Silent (SNP) | VAF 29/170 reads (17%) | catalogued as COSV57141515; called by muse, mutect2, varscan2
- VWA3B | c.3114G>A p.Q1038= | Silent (SNP) | VAF 54/325 reads (17%) | catalogued as COSV68245407; called by muse, mutect2, varscan2
- BLOC1S4 | c.*238C>A | 3'UTR (SNP) | VAF 9/49 reads (18%) | catalogued as COSV100296675; called by muse, mutect2, varscan2
- BOD1L1 | c.8105-18A>G | Intron (SNP) | VAF 28/131 reads (21%) | called by muse, mutect2, varscan2
- KANK1 | c.3996+59C>A | Intron (SNP) | VAF 26/161 reads (16%) | called by muse, mutect2, varscan2
- KCTD11 | c.*319T>C | 3'UTR (SNP) | VAF 26/229 reads (11%) | catalogued as COSV99341876; called by muse, mutect2, varscan2
- PRNP | c.*423G>T | 3'UTR (SNP) | VAF 11/66 reads (17%) | catalogued as COSV101057344; called by muse, mutect2, varscan2
- STX12 | c.471-126T>A | Intron (SNP) | VAF 27/186 reads (15%) | called by muse, mutect2, varscan2
- ZNF436 | c.-245T>G | 5'UTR (SNP) | VAF 33/128 reads (26%) | called by muse, mutect2, varscan2
